Surgical pathology report (de-identified scan), TCGA case TCGA-NJ-A55O, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Rush University, specimen TCGA-NJ-A55O-01A (Primary Tumor).

[page 1 of 9]
Procedure Location:

PATHOLOGY SURGICAL

Results

Status: Final result

ICD-0-3

adenocarcinoma, mucinous, NOS 8480/3

Site: lung, upper lobe c34.1

hw
11/7/12

Entry Date

[page 2 of 9]
Component Results

PATHOLOGY RESULT:

Department of Pathology

Final

Clinical Data Repository* This report may not match the original report
format

FINAL DIAGNOSIS

A. (Right upper lobe lung; lobectomy): Invasive adenocarcinoma, grade 1, with mucinous features, measuring 2.6 cm. Bronchial, vascular, parenchymal, and visceral pleural margins are all free of tumor. One of five peribronchial

[page 3 of 9]
lymph nodes positive for metastatic adenocarcinoma, measuring 0.4 cm with no extracapsular extension. Remainder of lung with benign meningotheelial-like rest. Stage pT1bN1 (PL0). See note.

B. (Right paratracheal tissue): Fragments of anthracotic lymph node tissue negative for tumor.

C. (Subcarinal lymph nodes): Fragments of anthracotic lymph node tissue negative for tumor.

INTRAOPERATIVE CONSULTATION

A. FROZEN: RIGHT UPPER LOBE, FROZEN ON TUMOR AND BRONCHIAL MARGINS: Invasive adenocarcinoma, bronchial margin negative for malignancy (A91-mass, A92-bronchial margin,

NOTE

[page 4 of 9]
A. The tumor cells are strongly positive for CK7, positive for TTF-1, and are negative for CK20 and CDX-2, which supports a lung primary.

Immunohistochemistry controls are examined and show appropriate reactivity.

Lung Cancer Summary

Specimen type: Lobectomy

Procedure: Right upper lobectomy

Specimen integrity: intact

Tumor location: Right upper lobe

Tumor focality: unifocal

Tumor size: 2.6 x 2.0 x 2.0 cm

Histologic type: Adenocarcinoma

Histologic grade: 1

Treatment effect: Not applicable

Status of margins:

[page 5 of 9]
Bronchial: Negative

Vascular: Negative

Parenchymal: Negative

Pleural: Negative

Visceral pleural invasion: absent

Lymphatic vascular invasion: absent

Lymph node status: positive (peribronchial)

Extension into other structures: absent

Non-neoplastic pathology: meningotheelial-like rest

TMN stage: pT1bN0(PLO)

GROSS DESCRIPTION

A. The specimen is labeled right upper lobe. Received fresh for frozen section is a 15.0 x 10.3 x 3.0 cm lobectomy specimen with multiple overlying staples margins in total measuring 15.5 cm in length. The visceral pleural surface is inked black and the specimen is sectioned to show a spiculated tan tumor measuring 2.6 x 2.0 x 2.0 cm located 0.2 cm from the overlying visceral pleura, 2.0 cm from the closest overlying staple margin and 3.0 cm from the

[page 6 of 9]
bronchial margin. The remainder of the lung tissue shows anthracosis and some mild congestion. No other discrete masses or lesions are identified. A touch prep of the tumor is performed and a portion is submitted for frozen section with the remnant wrapped and placed in cassette A91. A shave of the bronchial margin is submitted for frozen section with the remnant wrapped and placed in cassette A92. Additional cassettes are submitted as follows: A1-A2, sections of tumor and overlying visceral pleura; A3, section of tumor and adjacent lung; A4, stapled margin closest to tumor and vascular margin; A5, multiple peribronchial lymph nodes; A6, uninvolved lung.

B. The specimen is labeled right paratracheal tissue. Received in formalin are multiple irregular fragments of white-tan fibrous tissue and yellow adipose tissue (1.5 x 2.5 x 1.0 cm in aggregate) admixed with multiple fragments of black possible lymphoid tissue. All of the possible lymphoid tissue is submitted in cassettes B1-B5.

C. The specimen is labeled subcarinal nodes. Received in formalin are multiple irregular fragments of red-black possible lymphoid tissue measuring 1.8 x 1.5 x 0.4 cm in aggregate. All of the lymphoid tissue is submitted as follows: C1 - largest fragment bisected, C2 - one fragment bisected, C3 - 2 intact fragments.

SPECIMEN(S) RECEIVED

A: FROZEN: RIGHT UPPER LOBE, FROZEN ON TUMOR AND BRONCHIAL MARGINS

[page 7 of 9]
B: RIGHT PARATRACHEAL TISSUE

C: SUBCARINAL NODES

* The above listed tests (if any) were developed and the performance characteristics determined by Department of Pathology. These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays. (21 CFR 809.30(e))

OPERATIVE INFORMATION

DIAGNOSIS: LUNG NODULE; PROCEDURE: BRONCHOSCOPY FLEXIBLE FIBEROPTIC,
THORACOSCOPY VIDEO ASSISTED

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s): 162.3

CPT(s): A: 88309, 88331, 88332, 88334, 88342 ck7, 88342 ck20, 88342 ttf1,
88342 cdx2

B: 88307

C: 88307

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

[page 8 of 9]
PATHOLOGY SURGICAL

Lab and Collection Information

PATHOLOGY SURGICAL

Pathology

Procedure Location:

Source: NCI Genomic Data Commons file 158b24cb-3090-4ec5-b8ec-0cb1ded3cfcd (TCGA-NJ-A55O.FBB218E1-EB67-4C9D-8149-EE276C1E9BCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).